Somatic mutation profile of tumor specimen TCGA-AR-A1AR-01A (aliquot TCGA-AR-A1AR-01A-31D-A135-09) from TCGA case TCGA-AR-A1AR, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 50.6 years (18,482 days).
Specimen TCGA-AR-A1AR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 934db28d-2b10-43c8-820d-5b43cffc50aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A1AR-10A (Blood Derived Normal), aliquot TCGA-AR-A1AR-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de1057c2-bd6d-437d-8658-e18723d12bf3

The open-access MAF lists 53 somatic variants for this specimen: 39 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 11, Nonsense Mutation 4, Frame Shift Del 2, Intron 1, Splice Site 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPH | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV57736669; called by muse, mutect2
- BAZ2B | c.6352C>T p.Q2118* | Nonsense Mutation (SNP) | VAF 20/119 reads (17%) | catalogued as COSV58601776; called by muse, mutect2, varscan2
- BRF1 | c.1667G>A p.R556K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV59269238; called by muse, mutect2, varscan2
- C1orf94 | c.995G>A p.R332K (on ENST00000488417 / NM_001134734.2; = p.R142K on NM_032884.5) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV64914168; called by muse, mutect2, varscan2
- CALB2 | c.443A>T p.D148V | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV56939724; called by muse, mutect2, varscan2
- CENPF | c.1246C>A p.Q416K | Missense Mutation (SNP) | VAF 68/322 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV65275357, COSV65278713; called by muse, mutect2, varscan2
- CLCN3 | c.160+1G>T p.X54_splice | Splice Site (SNP) | VAF 49/170 reads (29%) | catalogued as rs1413196640, COSV61627256; called by muse, mutect2, varscan2
- COL6A6 | c.3580G>T p.V1194F | Missense Mutation (SNP) | VAF 110/520 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV62026584; called by muse, mutect2, varscan2
- DHRS2 | c.586A>G p.T196A | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as COSV51632122; called by muse, mutect2, varscan2
- ENO3 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.792); catalogued as rs1304120580, COSV56697659; called by muse, mutect2, varscan2
- EVPL | c.843G>T p.Q281H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV56911826; called by muse, mutect2, varscan2
- FLG | c.1337G>C p.R446T | Missense Mutation (SNP) | VAF 76/702 reads (11%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.519); catalogued as COSV64242534; called by muse, mutect2, varscan2
- FSHR | c.1888A>G p.T630A | Missense Mutation (SNP) | VAF 91/333 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs779291542, COSV58624572; called by muse, mutect2, varscan2
- GNPAT | c.1148T>G p.L383W | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV64153550; called by muse, mutect2, varscan2
- HDX | c.1934A>C p.K645T | Missense Mutation (SNP) | VAF 102/361 reads (28%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.991); catalogued as COSV52977339; called by muse, mutect2, varscan2
- ITGA10 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 111/490 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as rs782387856, COSV65197567, COSV65199314; called by muse, mutect2, varscan2
- ITIH4 | c.444G>T p.E148D | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56574667; called by muse, mutect2, varscan2
- KLRF1 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 74/230 reads (32%) | catalogued as COSV54380980; called by muse, mutect2, varscan2
- KNG1 | c.902T>C p.I301T | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as rs752033867, COSV53977366; called by muse, mutect2, varscan2
- LRSAM1 | c.2020G>C p.E674Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773487480, COSV55940380; called by muse, mutect2, varscan2
- MDGA2 | c.2774G>A p.R925H (on ENST00000399232 / NM_001113498.2; = p.R627H on NM_182830.4) | Missense Mutation (SNP) | VAF 69/307 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs367556844, COSV62077847; called by muse, mutect2, varscan2
- NPR3 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 137/371 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs780642601, COSV54088191; called by muse, mutect2, varscan2
- OR14K1 | c.941G>C p.R314T | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV51721401; called by muse, mutect2, varscan2
- OR5T1 | c.823A>C p.S275R | Missense Mutation (SNP) | VAF 23/432 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV57302939; called by muse, mutect2
- PTRHD1 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53230720; called by muse, mutect2, varscan2
- RPRD2 | c.1123G>T p.D375Y | Missense Mutation (SNP) | VAF 48/400 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV64820626, COSV64822759; called by muse, mutect2, varscan2
- SLC22A16 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 98/391 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs201910262, COSV57930282; called by muse, mutect2, varscan2
- SNRNP48 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV60939606; called by muse, mutect2, varscan2
- SSX5 | c.422C>A p.P141H (on ENST00000347757 / NM_175723.1; = p.P182H on NM_021015.4) | Missense Mutation (SNP) | VAF 202/669 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); catalogued as COSV61255314; called by muse, mutect2, varscan2
- TAX1BP1 | c.1448A>T p.N483I | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV55293614; called by muse, mutect2, varscan2
- TDRD9 | c.2384T>C p.L795P | Missense Mutation (SNP) | VAF 116/414 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV59148106; called by muse, mutect2, varscan2
- TFE3 | c.1523A>T p.D508V | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as COSV59947279; called by muse, mutect2, varscan2
- TINAG | c.1330G>T p.E444* | Nonsense Mutation (SNP) | VAF 43/195 reads (22%) | catalogued as COSV52510203; called by muse, mutect2, varscan2
- TP53 | c.268del p.S90Pfs*33 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as COSV52814290, COSV53089014; called by mutect2, pindel, varscan2
- TTC31 | c.960C>G p.F320L | Missense Mutation (SNP) | VAF 77/254 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.03); catalogued as COSV52035448; called by muse, mutect2, varscan2
- UCK2 | c.604A>T p.K202* | Nonsense Mutation (SNP) | VAF 70/420 reads (17%) | catalogued as COSV63315512; called by muse, mutect2, varscan2
- ZNF415 | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 72/253 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV54701671; called by muse, mutect2, varscan2
- NBPF15 | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 57/585 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.985); called by muse, varscan2
- RRAGB | c.499del p.Y167Tfs*34 (on ENST00000262850 / NM_016656.4; = p.Y139Tfs*34 on NM_006064.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 41/187 reads (22%) | called by mutect2, pindel, varscan2
- CMTM7 | c.381C>T p.S127= | Silent (SNP) | VAF 71/349 reads (20%) | catalogued as COSV58550911; called by muse, mutect2, varscan2
- LHX4 | c.846C>T p.G282= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as rs139479246, COSV55375700; called by muse, mutect2, varscan2
- LRRK2 | c.6471T>G p.A2157= | Silent (SNP) | VAF 55/140 reads (39%) | catalogued as COSV54154960; called by muse, mutect2, varscan2
- MYO1F | c.1917C>T p.P639= | Silent (SNP) | VAF 39/229 reads (17%) | catalogued as rs771930639, COSV57791573; called by muse, mutect2, varscan2
- OR5K2 | c.504C>T p.F168= | Silent (SNP) | VAF 165/636 reads (26%) | catalogued as COSV71143219, COSV71143540; called by muse, mutect2, varscan2
- PCDHA13 | c.2055C>T p.G685= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV56482120; called by muse, mutect2, varscan2
- PPL | c.922C>T p.L308= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV62047418; called by muse, mutect2, varscan2
- PTPRZ1 | c.867G>A p.Q289= | Silent (SNP) | VAF 126/531 reads (24%) | catalogued as COSV66437594; called by muse, mutect2, varscan2
- RTN2 | c.1446T>A p.I482= | Silent (SNP) | VAF 49/189 reads (26%) | catalogued as COSV55594282; called by muse, mutect2, varscan2
- TTYH1 | c.696C>T p.L232= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV56612176; called by muse, mutect2, varscan2
- ZFAND2B | c.174T>C p.P58= | Silent (SNP) | VAF 45/164 reads (27%) | catalogued as COSV54696403; called by muse, mutect2, varscan2
- GGNBP1 | chr6:33593078 C>A | 3'Flank (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- MIR1185-1 | n.50C>T | RNA (SNP) | VAF 80/394 reads (20%) | catalogued as rs565750013; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23402G>T | Intron (SNP) | VAF 11/53 reads (21%) | catalogued as COSV100529591; called by muse, mutect2, varscan2
